CCDI case PBBNCV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/609f9d96-8265-44c7-b73c-cda87116d772

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Large cell medulloblastoma: ICD-O-3 morphology code: 9474/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.9 years (1,077 days).

Biospecimens (3 samples)
- Sample 0DCZR5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCZR8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DCZR9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
